Gene-level copy-number profile of tumor specimen TCGA-KK-A8IK-01A from TCGA case TCGA-KK-A8IK, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 56.4 years (20,594 days).
Specimen TCGA-KK-A8IK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.a8c4ad42-a4de-4771-a660-cb0096527643.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KK-A8IK-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a71516da-f184-4380-aea5-48f8f3056f9b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 240; copy number 2: 7,869; copy number 3: 15,361; copy number 4: 26,901; copy number 5: 2,639; copy number 6: 4,240; copy number 7: 395; copy number 8: 1,586; copy number 9: 354; copy number 10: 220; copy number 16: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KK-A8IK-01A-11D-A363-01): tumor purity 0.96, ploidy 4.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:82,727,474–82,990,298, 5 genes: AC099506.2, AC099506.1, AC099506.3, RN7SL134P, AC125793.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 579 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:92,151–20,575,873, 354 genes, copy number 9 (within-gene range 1–9) (broad region; genes not listed).
- chr8:137,524,755–145,066,685, 220 genes, copy number 10 (broad region; genes not listed).
- chr9:8,700,595–8,963,077, 5 genes, copy number 16: AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1.

Autosomal genes at a single copy (total copy number 1): 240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
